Gene-level copy-number profile of tumor specimen C3N-02339-02 from CPTAC case C3N-02339, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.0 years (28,848 days).
Specimen C3N-02339-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 36d6504f-e81d-4670-a437-bf51deb79aca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02339-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/d88767a4-fb39-4a7a-945c-4faba1bdbe78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 16,486; copy number 2: 32,666; copy number 3: 7,425; copy number 4: 1,946; copy number 5: 90; copy number 7: 48; copy number 8: 60; copy number 9: 52; copy number 10: 44; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–25,089,151, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 297 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:159,231,435–159,233,377, 1 gene, copy number 5: PIP5K1P2.
- chr12:57,452,323–60,419,293, 73 genes, copy number 5 (broad region; genes not listed).
- chr12:62,260,338–72,728,844, 220 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr12:74,656,561–74,728,851, 3 genes, copy number 11: AC123904.2, AC123904.1, AC123904.3.

Autosomal genes at a single copy (total copy number 1): 13,980. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
